Surgical pathology report (de-identified scan), TCGA case TCGA-G3-AAV1, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Alberta Health Services, specimen TCGA-G3-AAV1-01A (Primary Tumor).

[page 1 of 3]
CONFIDENTIAL

SURGICAL PATHOLOGY REPORT

Time Collected		Time Received	
Time Reported		Time Transmitted	
Order Number		Ordering Provider	
Status	Final	Relevant Information	
Copied To		Location	

Report Patient Name:
Demographics (for verification purposes) Date of Birth:
Sex: M

ADDENDUM REPORT

*****Addendum Report*****

Accession Number
Collected Date/Time
Received Date/Time
Pathologist
Addendum Reason
results of special stains
Addendum Diagnosis

A. Liver, Segment 6, Partial Hepatectomy:

- Hepatocellular carcinoma, poorly differentiated, 5.0 x 4.5 x 4.5 cm.
- Tumor perforates visceral peritoneum (pT4).
- Venous and lymphatic space invasion present.
- Intralymphatic carcinoma present within 0.24 cm of parenchymal resection margin.
- Background liver with cirrhosis, consistent with the known history of hepatitis B.
- Focal non-necrotizing granuloma, special stains negative for infectious organisms.
- Please see comment and synoptic report.

B. Right Diaphragm, Excision:

- Skeletal muscle and fibroadipose tissue with adherent fibrinous debris and reactive mesothelial hyperplasia.
- Rare detached cauterized fragments of hepatocellular carcinoma, present within adherent blood clot.
- No tissue invasion by tumor identified.

C. "Adrenal Gland", Right Excision.

- Intravenous embolus of hepatocellular carcinoma, involving a large vein within adipose tissue.
- No adrenal gland identified.
- Please see comment.

Reported by:
Electronically signed by:
Verified:

Addendum Discussion

An addendum is issued to report the results of special stains for microorganisms, done to evaluate a non-necrotizing granuloma (block A10). Ziehl-Neelsen and Grocott's stains are negative for acid-fast bacilli and fungi, respectively. However, negative stains do not rule out the possibility of an infectious etiology.

There are no other changes to the original report. Please refer to the comment section of the original report for additional details.

*****Surgical Pathology Report*****

Accession Number
Collected Date/Time

ICD O-3
Carcinoma, hepatocellular NOS
8170/3
Site Liver C22.0
J 5/20/14

[page 2 of 3]
Received Date/Time
Pathologist
Specimen Description
A. Liver segment 6 at 0
B. Right diaphragm and tumor at
C. Right adrenal at
Clinical Information
Hepatitis B+, hepatocellular carcinoma.

Diagnosis

- A. Liver, Segment 6, Partial Hepatectomy:
- Hepatocellular carcinoma, poorly differentiated, 5.0 x 4.5 x 4.5 cm.
- Tumor perforates visceral peritoneum (pT4).
- Venous and lymphatic space invasion present.
- Intralymphatic carcinoma present within 0.24 cm of parenchymal resection margin.
- Background liver with cirrhosis, consistent with the known history of hepatitis B.
- Focal non-necrotizing granuloma, pending special stains.
- Please see comment and synoptic report.
- B. Right Diaphragm, Excision:
- Skeletal muscle and fibroadipose tissue with adherent fibrinous debris and reactive mesothelial hyperplasia.
- Rare detached cauterized fragments of hepatocellular carcinoma, present within adherent blood clot.
- No tissue invasion by tumor identified.
- C. "Adrenal Gland", Right Excision.
- Intravenous embolus of hepatocellular carcinoma, involving a large vein within adipose tissue.
- No adrenal gland identified.
- Please see comment.

Reported by:

Electronically signed by:

Verified:

Synoptic Report

Specimen:

Liver

PROCEDURE:

Partial hepatectomy

*Minor hepatectomy (less than 3 segments)

TUMOR SIZE:

Greatest dimension: 5.0 cm

*Additional dimensions: 4.5 x 4.5 cm

TUMOR FOCALITY:

Solitary (specify location): segment 6

HISTOLOGIC TYPE:

Hepatocellular carcinoma

HISTOLOGIC GRADE:

GIII: Poorly differentiated

TUMOR EXTENSION (select all that apply):

Tumor directly invades other adjacent organs: tumor penetrates through visceral peritoneum, and was adherent to diaphragm and periadrenal adipose tissue intra-operatively

PRIMARY TUMOR (pT):

pT4: Tumor(s) with direct invasion of adjacent organs other than the gallbladder or perforation of visceral peritoneum

REGIONAL LYMPH NODES (pN):

pNX: Cannot be assessed

DISTANT METASTASIS (pM):

pMX: Cannot be assessed

MARGINS:

Parenchymal margin uninvolved by invasive carcinoma

Distance of invasive carcinoma from closest margin: 2.4 mm

Bile duct margin cannot be assessed

*VENOUS (LARGE VESSEL) INVASION (V):

*Present

*ADDITIONAL PATHOLOGIC FINDINGS:

*Cirrhosis/fibrosis

*Hepatitis (specify type): hepatitis B

[page 3 of 3]
non-necrotizing granuloma

*COMMENT(S):

please see comment in main report

Gross Description

Received are specimen containers A to C. All requisitions and specimen containers are labelled with the patient's name, The cassettes and identifiers are labelled with the Surgical Number

A. The specimen is received fresh and is subsequently placed into formalin, designated as "A - liver segment 6". The specimen consists of a 131.8 gram, 10.0 x 5.6 x 5.9 cm portion of liver. The capsular surface is smooth and predominantly tan with a focal hemorrhagic area. The resection margin is painted blue. Sectioning reveals a 5.0 x 4.5 x 4.5 cm well demarcated multinodular mass which replaces most of the resected liver. The nodules are variably yellow green to tan with foci of hemorrhage and necrosis. The mass comes to within 1.0 cm to the parenchymal resection margin. The remaining liver parenchyma is brown, tan, slightly firm, and nodular. Sections are submitted as follows:
A1-4. mass in relation to parenchymal resection margin with A1 demonstrating area of necrosis

A5-7. lesion in relation to the capsule, A5-6 demonstrating areas of hemorrhage

A8-10. representative sections from remaining liver parenchyma

B. The specimen is received fresh and is subsequently placed into formalin, designated as "B - right diaphragm and tumor". The specimen consists of a 4.5 x 3.3 x 0.9 cm irregular portion of grey-tan to dark brown tissue. One surface is grey-tan and smooth. The opposite surface is dark brown and roughened. Sectioning reveals a central area that is light brown and homogeneous. Six representative sections are submitted in B1-B3. The remaining specimen is submitted in toto following initial histologic examination in B4-B6.

C. The specimen is received fresh and is subsequently placed into formalin, designated as "C - right adrenal". The specimen consists of multiple portions of fibrofatty tissue measuring in aggregate 5.0 x 3.0 x 1.0 cm. The cut surface shows predominantly yellow adipose tissue with areas of semi firm tan to hemorrhagic friable tissue. A definitive adrenal gland is not identified. Sections are submitted as follows:

C1. slightly firm tan to hemorrhagic tissue submitted in toto

C2-3. remainder of tissue submitted in toto

Pathologist Comment

The hepatocellular carcinoma shows a classical trabecular / sinusoidal growth pattern with a few foci of acinar growth. The tumor is morphologically heterogeneous, ranging from moderately differentiated to poorly differentiated with anaplastic cytology. While the main tumor mass is excised with a 7 mm margin, there is extensive lymphovascular invasion beyond the tumor capsule, and intralymphatic tumor is present within 2.4 mm of the parenchymal resection margin. Cauterized fragments of tumor are present in blood clot adherent to the diaphragm, but these may represent intraoperative artifact, and no true invasion of the diaphragm is identified. Finally, the specimen designated "adrenal" shows adipose tissue with a large intravenous tumor embolus. No adrenal gland is identified. Per discussion with Dr. this tissue was taken from the fat plane between the liver and the adrenal, and therefore this may represent local extension of tumor.

Finally, the background liver shows cirrhosis (consistent with the known history of hepatitis B) as well as a single well-formed non-necrotizing granuloma. Special stains for infectious organisms are pending, and will be reported as an addendum.

In case ancillary studies are desired, tumor block information is listed below:

Best tumor block: A6

Best normal block: A8

Accession Number
Encounter Number
Patient Location

Source: NCI Genomic Data Commons file c96e1a89-e3a1-4af8-ac9a-4e8fda90a8ae (TCGA-G3-AAV1.0124A3C7-B294-464E-831D-3E4738E3F305.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).